Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A1-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Liver segments IV through VIII (1,900 grams; 22 x 14 x 9 cm), liver segment III (15 grams; 4.5 x 3 x 2.7 cm), and biopsy specimen from the peritoneum (1 x 0.8 x 0.4 cm). A1, B1, B2, B3, B4, C1

DIAGNOSIS:

Liver, segments IV through VIII, resection: Grade 2 (of 4) hepatocellular carcinoma, usual type, forming a multinodular mass, 16 x 15 x 11 cm, with multiple (5) satellite nodules ranging in size from 0.5 cm to 1.5 cm. The tumor is located in segments IV through VIII. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being approximately 1 mm microscopically. Extensive extratumoral vascular invasion is identified. The tumor is not encapsulated, infiltration of parenchyma being of the infiltrating type. The non-neoplastic liver will be assessed on permanent sections and an addendum will be issued.

Liver, segment III, excision: Bile duct hamartoma (1.2 x 1.1 x 1 cm).

Peritoneum, biopsy: Inflammatory adhesion, negative for tumor.

Specimen photographed in lab.
PHOTOGRAPHED IN LAB

ADDENDUM:

The non-neoplastic liver shows no features of either primary or chronic liver disease.

Seen with Dr.

ICD-O-3
carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 lw
9/22/11

Source: NCI Genomic Data Commons file b458bb6e-9898-492d-9275-eb4d87324a67 (TCGA-DD-A3A1.EAB38F5C-4399-48DE-A4F5-18B7CB982689.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).